Gene-level copy-number profile of tumor specimen TCGA-52-7622-01A from TCGA case TCGA-52-7622, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.4 years (22,807 days).
Specimen TCGA-52-7622-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.4af73a59-07ad-4d9c-863b-833e9db59b1f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-52-7622-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4c3fb345-f76d-48b4-8ac5-061b1e4a791e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 514; copy number 2: 10,350; copy number 3: 7,780; copy number 4: 25,858; copy number 5: 8,935; copy number 6: 4,583; copy number 7: 415; copy number 8: 176; copy number 9: 485; copy number 10: 197; copy number 12: 36; copy number 13: 6; copy number 14: 429; copy number 39: 50.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-52-7622-01A-11D-2121-01): tumor purity 0.39, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,203 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:168,858,659–198,222,513, 593 genes, copy number 9–39 (broad region; genes not listed).
- chr8:126,325,454–128,564,679, 36 genes, copy number 12: AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr9:8,700,595–9,091,245, 6 genes, copy number 13: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3.
- chr9:12,287,320–22,214,672, 163 genes, copy number 14 (broad region; genes not listed).
- chr9:26,642,697–28,670,286, 29 genes, copy number 14 (within-gene range 8–14): AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1.
- chr9:32,293,558–43,045,120, 376 genes, copy number 9–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 514. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
